HCMI case HCM-BROD-0745-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1afc9344-bb0c-4074-a7d8-dc941a47266d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,306 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic N: N3c; AJCC pathologic stage: Stage IIIC; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 4 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 78 days; Days to treatment end: 141 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab + Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 148 days; Days to treatment end: 148 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Binimetinib + Encorafenib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 186 days; Days to treatment end: 526 days (1.4 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 69.4 years (25,339 days); Days to diagnosis: 33 days; Satellite nodule present: Present.
   Pathology details: Breslow thickness category: <=1 mm; Lymph nodes positive: 1; Lymph nodes tested: 26.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 550 days (1.5 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 204.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Negative.
- TP53 mutation, nos: Positive; Amino-acid change: E336*.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 99 kg; Height: 165 cm; BMI: 36.4.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0745-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0745-C43-06B-02-S2-HE: Section location: Bottom; Percent tumor cells: 69; Percent tumor nuclei: 78; Percent normal cells: 19; Percent necrosis: 0; Percent stromal cells: 12; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0745-C43-06B-02-S1-HE: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 73; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 8; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0745-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0745-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
